Surgical pathology report (de-identified scan), TCGA case TCGA-CR-5247, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-5247-01A (Primary Tumor).

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

Accession Number: [REDACTED]

Final Report

DIAGNOSIS: 1) TONSIL, LEFT, BIOPSY: INVOLVED BY MODERATELY-DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA (SEE COMMENT).

COMMENT: Tumor is seen in lymphovascular spaces.

Electronically signed by: [REDACTED]

CLINICAL DATA

Clinical Features: unspecified

Operator: Dr. [REDACTED]

Operation: unspecified

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: left tonsil ([REDACTED])

GROSS DESCRIPTION:

1) SOURCE: Tonsil, Left. Received fresh is a fragment of pink-tan soft tissue measuring 1.5 x 1.0 x 0.3 cm. The specimen is entirely submitted. Summary of sections: 1A, 1/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

Date In Lab: [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file bab40ea7-4cca-47de-9885-095d4f0fd4a5 (TCGA-CR-5247.158A250B-4D70-4E5F-9E22-7EC67A7F4697.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).